Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5115, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5115-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, RADICAL NEPHRECTOMY –

- A. A. RENAL CELL CARCINOMA, CLEAR CELL TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 3 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 9.0 cm.
- D. THE NEOPLASM IS CONFINED TO THE KIDNEY WITHOUT EXTRACAPSULAR INVASION
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. NON-NEOPLASTIC KIDNEY SHOWS NON-SPECIFIC CHANGES RELATED TO PROXIMITY TO THE TUMOR
- H. TNM STAGE: pT2 NX MX.

Source: NCI Genomic Data Commons file 0f5d3963-d4dc-4c85-816e-19287b3e7506 (TCGA-B0-5115.6BDE77A8-12B0-4931-868E-E383F8489096.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).